Somatic mutation profile of tumor specimen TCGA-X6-A8C7-01A (aliquot TCGA-X6-A8C7-01A-11D-A36J-09) from TCGA case TCGA-X6-A8C7, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Synovial sarcoma, biphasic; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 24.9 years (9,104 days).
Specimen TCGA-X6-A8C7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d87f8a1f-857f-4355-ade7-b06296bb4865.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-X6-A8C7-10A (Blood Derived Normal), aliquot TCGA-X6-A8C7-10A-01D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/796c71ff-e299-44a0-acf9-699dc7cae003

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Splice Site 2, Frame Shift Ins 1, Silent 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATG16L1 | c.390-2A>G p.X130_splice | Splice Site (SNP) | VAF 14/39 reads (36%) | catalogued as COSV100731321, COSV99052237; called by muse, mutect2, varscan2
- ATP2B1 | c.3304C>A p.R1102S | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.065); catalogued as COSV53806213, COSV99665778; called by muse, mutect2
- HERC1 | c.12256A>G p.T4086A | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as COSV101496595; called by muse, mutect2, varscan2
- POU2F2 | c.29-1G>A p.X10_splice | Splice Site (SNP) | VAF 22/86 reads (26%) | catalogued as COSV100657370; called by muse, mutect2, varscan2
- TRDN | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1371219098, COSV100522147; called by muse, mutect2, varscan2
- ZNF608 | c.2920A>T p.S974C | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.386); catalogued as COSV100101768; called by muse, mutect2
- CEP85 | c.409G>T p.A137S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, varscan2
- DBN1 | c.1345dup p.A449Gfs*3 | Frame Shift Ins (INS) | VAF 15/39 reads (38%) | called by mutect2, pindel, varscan2
- TTLL11 | c.810T>A p.G270= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as rs1261443665, COSV100388828; called by muse, mutect2, varscan2
- FAM21FP | n.1129G>C | RNA (SNP) | VAF 80/177 reads (45%) | called by muse, mutect2, varscan2
